Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1MP, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1MP-01A (Primary Tumor).

1CD-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: cervix, NOS C53.9 2/24/11 *lu*

Patient Name:

DOB:

MRN:

Patient ID:

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

FINAL

Patient Name:

Address:

Gender:

DOB:

Service:

Gynecology

Location:

MRN:

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s): M.D.

DIAGNOSIS:

UTERUS, CERVIX, RADICAL HYSTERECTOMY

- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 4.3 CM IN GREATEST DIMENSION, INVADING TO A MAXIMUM DEPTH OF 1.4 CM OUT OF A TOTAL CERVICAL THICKNESS OF 2.4 CM
- EXTENSIVE LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED
- PARAMETRIA, NEGATIVE FOR MALIGNANCY
- MARGINS OF RESECTION ARE FREE OF TUMOR

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY

- SECRETORY ENDOMETRIUM
- NO EVIDENCE OF MALIGNANCY

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY

- ADENOMYOSIS
- NO EVIDENCE OF MALIGNANCY

LYMPH NODES, LEFT PELVIC, DISSECTION

- METASTATIC SQUAMOUS CARCINOMA IN 3 OF 15 LYMPH NODES (3/15)

LYMPH NODES, LEFT COMMON, DISSECTION

- METASTATIC SQUAMOUS CARCINOMA IN 1 OF 9 LYMPH NODES (1/9)

LYMPH NODES, LEFT PERIAORTIC, DISSECTION

- METASTATIC SQUAMOUS CARCINOMA IN 1 OF 14 LYMPH NODES (1/14)

LYMPH NODES, RIGHT PELVIC, DISSECTION

- METASTATIC SQUAMOUS CARCINOMA IN 1 OF 15 LYMPH NODES (1/15)

LYMPH NODE, RIGHT PRECAVAL, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

MD

***Report Electronically Reviewed and Signed Out By MD

Printed from

Source: NCI Genomic Data Commons file e9d56319-f455-4561-bfb2-a68f18d74f81 (TCGA-C5-A1MP.AA5A1858-A926-4CCE-BC1C-1F1E964EAA96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).